Somatic mutation profile of tumor specimen HCM-CSHL-0189-C25-01A (aliquot HCM-CSHL-0189-C25-01A-11D-A78L-36) from HCMI case HCM-CSHL-0189-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 63.9 years (23,328 days).
Specimen HCM-CSHL-0189-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0f89c8f-552b-4844-83f2-e63b9cebc46a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0189-C25-11A (Solid Tissue Normal), aliquot HCM-CSHL-0189-C25-11A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b712d7c5-e78f-48ee-a213-3b3ba6175e92

The open-access MAF lists 57 somatic variants for this specimen: 33 protein-altering or splice-affecting, 17 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 17, Intron 3, Splice Site 3, 5'Flank 2, In Frame Del 2, 5'UTR 1, Splice Region 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 36/282 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 21/145 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2687C>T p.P896L | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768650484, COSV54450847; called by muse, mutect2
- ATM | c.8787-1G>A p.X2929_splice | Splice Site (SNP) | VAF 27/284 reads (10%) | catalogued as CS991313, COSV53759148, COSV53771313; called by muse, mutect2
- DLGAP2 | c.788C>A p.A263E | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.482); catalogued as rs375416274, COSV101422983, COSV70099599, COSV99073642; called by muse, mutect2, varscan2
- EID3 | c.583A>T p.M195L | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs750721767; called by muse, mutect2, varscan2
- HTR3C | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 38/302 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369394644; called by muse, mutect2, varscan2
- IKZF3 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 44/423 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); catalogued as rs1171389897, COSV53105779; called by muse, mutect2, varscan2
- LCE2A | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 39/458 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs201971844; called by muse, mutect2
- MORC2 | c.847C>T p.R283C (on ENST00000397641 / NM_001303256.3; = p.R221C on NM_014941.3) | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765158896, COSV99309970; called by muse, mutect2
- MROH5 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs1212618816; called by muse, mutect2
- MYH4 | c.5585G>A p.R1862H | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs538270849, COSV55126101; called by muse, mutect2, varscan2
- PCDH17 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 46/382 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV100932118; called by muse, mutect2, varscan2
- PRPF31 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 45/381 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415051331; called by muse, mutect2, varscan2
- PTOV1 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as rs774909974, COSV99681998; called by muse, mutect2, varscan2
- RAC2 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 47/361 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); catalogued as COSV50774054; called by muse, mutect2, varscan2
- SLC16A7 | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370627884; called by muse, mutect2, varscan2
- ADARB2 | c.238_267del p.A80_A89del | In Frame Del (DEL) | VAF 20/174 reads (11%) | called by mutect2, pindel
- BRCC3 | c.316-2A>G p.X106_splice | Splice Site (SNP) | VAF 35/144 reads (24%) | called by muse, mutect2, varscan2
- CPSF1 | c.1930_1935del p.A644_P645del | In Frame Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- DBN1 | c.1880-7G>A | Splice Region (SNP) | VAF 23/193 reads (12%) | called by muse, mutect2, varscan2
- DMRT2 | c.248dup p.P84Tfs*103 | Frame Shift Ins (INS) | VAF 12/64 reads (19%) | called by mutect2, varscan2
- DNAH7 | c.9557A>C p.Q3186P | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FATE1 | c.106+1G>T p.X36_splice | Splice Site (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- GLMN | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 34/325 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC1 | c.3470C>A p.A1157D (on ENST00000611571 / NM_001371720.1; = p.A168D on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/425 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MUC1 | c.3469G>A p.A1157T (on ENST00000611571 / NM_001371720.1; = p.A168T on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/403 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- MYOM1 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.201); called by muse, varscan2
- PCDHB10 | c.1892G>A p.S631N | Missense Mutation (SNP) | VAF 96/784 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- SETD6 | c.593C>A p.A198D (on ENST00000219315 / NM_001160305.4; = p.A174D on NM_024860.3) | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); called by muse, mutect2
- TBP | c.708A>C p.K236N | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF662 | c.155A>T p.Y52F | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF813 | c.145A>G p.I49V | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- APLP1 | c.1281G>A p.T427= | Silent (SNP) | VAF 33/289 reads (11%) | catalogued as rs1177115298; called by muse, mutect2, varscan2
- BCL11A | c.264A>G p.S88= | Silent (SNP) | VAF 18/438 reads (4%) | called by muse, mutect2
- CPSF3 | c.90C>T p.L30= | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as rs143561900; called by muse, mutect2, varscan2
- FOXK1 | c.351C>T p.L117= | Silent (SNP) | VAF 37/239 reads (15%) | catalogued as rs1266818481, COSV100195636; called by muse, mutect2, varscan2
- GAL3ST1 | c.438C>T p.Y146= | Silent (SNP) | VAF 38/376 reads (10%) | catalogued as rs1228915123, COSV58891825; called by muse, mutect2, varscan2
- GREB1 | c.1443G>A p.A481= | Silent (SNP) | VAF 28/312 reads (9%) | catalogued as rs977349859, COSV52193610; called by muse, mutect2
- GRIK2 | c.915G>A p.P305= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as rs145542805, COSV100028502; called by muse, mutect2, varscan2
- HSPG2 | c.12483C>T p.G4161= | Silent (SNP) | VAF 40/276 reads (14%) | called by muse, mutect2, varscan2
- KNDC1 | c.5001C>T p.H1667= | Silent (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2, varscan2
- LAMC1 | c.1812A>G p.V604= | Silent (SNP) | VAF 27/217 reads (12%) | called by muse, mutect2, varscan2
- MTNR1A | c.240G>A p.P80= | Silent (SNP) | VAF 46/454 reads (10%) | catalogued as rs149418383; called by muse, mutect2, varscan2
- OR2T12 | c.759C>A p.G253= | Silent (SNP) | VAF 57/509 reads (11%) | called by muse, mutect2, varscan2
- PRSS56 | c.123G>A p.A41= | Silent (SNP) | VAF 29/189 reads (15%) | catalogued as rs959302495, COSV51323402; called by muse, mutect2, varscan2
- SVEP1 | c.3348G>A p.S1116= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as rs369614705; called by muse, mutect2, varscan2
- TENM3 | c.7872G>A p.A2624= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as rs367925910; called by muse, mutect2, varscan2
- TRIM64 | c.1215A>G p.Q405= | Silent (SNP) | VAF 37/753 reads (5%) | catalogued as COSV59839961; called by muse, mutect2
- UNC5D | c.2235G>T p.G745= | Silent (SNP) | VAF 19/165 reads (12%) | catalogued as COSV54775211; called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916470 G>A | 5'Flank (SNP) | VAF 25/202 reads (12%) | catalogued as COSV58120837, COSV58125529; called by muse, mutect2, varscan2
- CLDND1 | c.-18-217A>T | Intron (SNP) | VAF 22/181 reads (12%) | called by muse, mutect2, varscan2
- DKC1 | c.1260-124A>T | Intron (SNP) | VAF 40/167 reads (24%) | called by muse, mutect2, varscan2
- ERFL | chr19:41928894 C>G | 5'Flank (SNP) | VAF 18/170 reads (11%) | called by muse, mutect2, varscan2
- LNPEP | c.-73C>G | 5'UTR (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2, varscan2
- MRPS17P9 | n.64dup | RNA (INS) | VAF 22/84 reads (26%) | called by mutect2, pindel, varscan2
- TCTN2 | c.1984+33G>A | Intron (SNP) | VAF 43/199 reads (22%) | called by muse, mutect2, varscan2
